Somatic mutation profile of tumor specimen C3N-02030-02 (aliquot CPT0133770011) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e98ad453-30bf-4a46-beb4-95e8d304ca39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77c15f2b-f4f0-4360-9c1f-7cb5bad36494

The open-access MAF lists 643 somatic variants for this specimen: 445 protein-altering or splice-affecting, 122 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 304, Silent 122, Frame Shift Del 82, Intron 46, Frame Shift Ins 25, Nonsense Mutation 20, 3'UTR 9, RNA 8, 5'UTR 6, Splice Site 5, In Frame Del 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 132/385 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 61/128 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 131/404 reads (32%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 137/466 reads (29%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 121/393 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 44/230 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 260/577 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 113/362 reads (31%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 27/754 reads (4%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 163/281 reads (58%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 72/278 reads (26%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 205/640 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 64/241 reads (27%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 108/344 reads (31%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 169/572 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 22/101 reads (22%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, varscan2
- CHD4 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 21/610 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58907984; called by muse, mutect2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- CNTN4 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 19/588 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329114875, COSV61872600; called by muse, mutect2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 54/134 reads (40%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 181/571 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- CTU1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70292317; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 136/441 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCAF13 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs868133848; called by muse, mutect2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 132/357 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 147/589 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 45/158 reads (28%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 56/178 reads (31%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 138/426 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 223/688 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 260/920 reads (28%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 118/389 reads (30%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 40/124 reads (32%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- GPS2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1349552330; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 39/111 reads (35%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ISLR2 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.482); catalogued as rs1435695204; called by muse, mutect2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 65/231 reads (28%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM2B | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV65639498; called by muse, mutect2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 90/364 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 132/423 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 46/169 reads (27%) | catalogued as rs1321319432; called by mutect2, pindel
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 98/306 reads (32%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MKRN3 | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs148583347; called by muse, mutect2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 167/534 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NAE1 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51975146; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 177/530 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NYX | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 81/904 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs139601761, COSV61181120; called by muse, mutect2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 27/123 reads (22%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 132/581 reads (23%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 128/403 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 159/489 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 53/324 reads (16%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 37/158 reads (23%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 122/443 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDCD11 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as COSV63934457; called by muse, mutect2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 43/101 reads (43%) | catalogued as rs759495724; called by mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 86/440 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 54/190 reads (28%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 42/124 reads (34%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 104/476 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2, varscan2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PPP4R3B | c.1478del p.L493* | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs749912209; called by mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 192/584 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 196/598 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 120/490 reads (24%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 133/385 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 53/128 reads (41%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 62/359 reads (17%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 54/179 reads (30%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 195/583 reads (33%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 141/628 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 34/143 reads (24%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 68/215 reads (32%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 177/558 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 64/231 reads (28%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TTN | c.81355A>G p.M27119V (on ENST00000591111; = p.M19695V on NM_003319.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | PolyPhen benign (0.085); catalogued as rs1388314469; called by muse, mutect2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- UVRAG | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs759030935; called by muse, mutect2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 134/484 reads (28%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 82/268 reads (31%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZNF451 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 11/239 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62596560; called by muse, mutect2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 83/271 reads (31%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ZNF714 | c.1655G>A p.G552D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV52514038; called by muse, mutect2
- ABCB8 | c.1193G>A p.G398D (on ENST00000297504 / NM_001282291.2; = p.G381D on NM_007188.5) | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 184/533 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 80/351 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM4 | c.990del p.D331Tfs*14 | Frame Shift Del (DEL) | VAF 43/272 reads (16%) | called by mutect2, pindel, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 170/564 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 72/222 reads (32%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- ALDH2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ANKRD30BL | c.581del p.N194Mfs*69 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | called by mutect2, pindel, varscan2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 117/400 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 41/397 reads (10%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 88/277 reads (32%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.5174G>A p.S1725N | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 60/186 reads (32%) | called by mutect2, pindel, varscan2
- ATM | c.3724A>G p.T1242A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATOH1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BAZ1A | c.3694G>T p.D1232Y | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- BRIX1 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 169/608 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2orf72 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 14/425 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CATSPERE | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 53/141 reads (38%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 94/276 reads (34%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 55/185 reads (30%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 153/452 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG1 | c.1408A>G p.N470D | Missense Mutation (SNP) | VAF 25/480 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.061); called by muse, mutect2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 64/279 reads (23%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 49/190 reads (26%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 107/390 reads (27%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 18/75 reads (24%) | called by pindel, varscan2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 103/413 reads (25%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 134/707 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DHTKD1 | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 21/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH9 | c.4961T>C p.L1654P | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 83/287 reads (29%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2299del p.M767* | Frame Shift Del (DEL) | VAF 15/140 reads (11%) | called by mutect2, pindel, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 47/163 reads (29%) | called by mutect2, pindel, varscan2
- EXOSC3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 36/612 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 191/608 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 47/233 reads (20%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 67/296 reads (23%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 116/328 reads (35%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 163/475 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 190/1050 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 89/385 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 53/203 reads (26%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 61/213 reads (29%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2152G>T p.G718W (on ENST00000265755 / NM_016328.3; = p.G703W on NM_005685.4) | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 77/293 reads (26%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 165/523 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HSPG2 | c.13052G>T p.G4351V | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 83/280 reads (30%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 27/161 reads (17%) | called by mutect2, pindel
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 161/452 reads (36%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 51/190 reads (27%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 76/323 reads (24%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 45/522 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 132/855 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 54/161 reads (34%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | called by pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEPR | c.2722T>C p.C908R | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.798G>T p.L266F (on ENST00000528054; = p.L235F on NM_019839.5) | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 63/469 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 178/579 reads (31%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- MAST4 | c.2833A>G p.S945G (on ENST00000403625 / NM_001164664.2; = p.S756G on NM_015183.3) | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MC5R | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEGF8 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 187/592 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 61/589 reads (10%) | called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MLXIP | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 55/205 reads (27%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 96/330 reads (29%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 36/122 reads (30%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 112/415 reads (27%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 51/135 reads (38%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 170/489 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA2 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 211/598 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 128/391 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- PDE8A | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 101/535 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 65/197 reads (33%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 147/468 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- POM121 | c.417T>G p.S139R | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP1R18 | c.1501del p.A501Lfs*105 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 65/470 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 96/359 reads (27%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRPF40A | c.383del p.P128Lfs*13 | Frame Shift Del (DEL) | VAF 34/247 reads (14%) | called by mutect2, pindel, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 67/239 reads (28%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 126/442 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 45/155 reads (29%) | called by mutect2, pindel, varscan2
- REV3L | c.1700T>C p.L567S | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- REXO5 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RFTN1 | c.934A>G p.S312G | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 22/96 reads (23%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 199/690 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENON | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 26/467 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 87/300 reads (29%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 52/80 reads (65%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK3 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 250/780 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 36/157 reads (23%) | called by mutect2, varscan2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- SNX32 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 108/366 reads (30%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 141/528 reads (27%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 60/232 reads (26%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 245/815 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENT5A | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- TEX9 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); called by muse, mutect2
- THPO | c.1166G>T p.R389M (on ENST00000649095 / NM_001290003.1; = p.R249M on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 44/168 reads (26%) | called by mutect2, pindel, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMED5 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- TMEM106A | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 87/306 reads (28%) | called by mutect2, pindel, varscan2
- TMEM132A | c.2209C>T p.P737S (on ENST00000453848 / NM_178031.3; = p.P738S on NM_017870.4) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- TMEM178B | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 121/389 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 154/438 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 98/400 reads (25%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 42/132 reads (32%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 84/284 reads (30%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 69/205 reads (34%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- VPS13C | c.1972C>T p.Q658* (on ENST00000644861 / NM_020821.3; = p.Q615* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 57/172 reads (33%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX2 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 46/193 reads (24%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- ZNF121 | c.236A>C p.Q79P | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF354A | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 49/181 reads (27%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 134/380 reads (35%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1650A>G p.K550= | Silent (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 101/252 reads (40%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2526A>G p.E842= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs1257678021; called by muse, mutect2, varscan2
- ATPAF2 | c.459T>G p.L153= | Silent (SNP) | VAF 31/713 reads (4%) | called by muse, mutect2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 101/269 reads (38%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 47/191 reads (25%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 153/542 reads (28%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 51/232 reads (22%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 87/264 reads (33%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 186/570 reads (33%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP350 | c.8976C>T p.N2992= | Silent (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- COL16A1 | c.2874C>T p.D958= | Silent (SNP) | VAF 26/279 reads (9%) | called by muse, mutect2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 82/263 reads (31%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 135/437 reads (31%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 85/243 reads (35%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 195/693 reads (28%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 82/296 reads (28%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 110/605 reads (18%) | called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 70/248 reads (28%) | called by muse, mutect2, varscan2
- HABP2 | c.456T>C p.P152= | Silent (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 106/352 reads (30%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HCRTR1 | c.615C>T p.R205= | Silent (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HOOK3 | c.666A>G p.V222= | Silent (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 60/199 reads (30%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 155/435 reads (36%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 88/263 reads (33%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- JMJD1C | c.6162T>G p.P2054= | Silent (SNP) | VAF 26/734 reads (4%) | catalogued as COSV59517283; called by muse, mutect2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 63/133 reads (47%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 104/461 reads (23%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 57/283 reads (20%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 129/408 reads (32%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LORICRIN | c.456G>T p.S152= | Silent (SNP) | VAF 24/634 reads (4%) | catalogued as rs1273657847; called by muse, mutect2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1195603578; called by mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 233/718 reads (32%) | called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAP3K13 | c.2709G>A p.S903= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs777826535; called by muse, mutect2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 120/284 reads (42%) | called by muse, mutect2, varscan2
- MED13 | c.5769T>C p.F1923= | Silent (SNP) | VAF 53/122 reads (43%) | called by muse, mutect2, varscan2
- MFSD12 | c.952C>T p.L318= | Silent (SNP) | VAF 13/314 reads (4%) | called by muse, mutect2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 155/459 reads (34%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 107/262 reads (41%) | called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 104/382 reads (27%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 112/291 reads (38%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 39/184 reads (21%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 94/339 reads (28%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 120/520 reads (23%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1590C>A p.R530= | Silent (SNP) | VAF 28/1026 reads (3%) | catalogued as rs144645252, COSV100696898; called by muse, mutect2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 91/271 reads (34%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 232/566 reads (41%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 101/338 reads (30%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 68/327 reads (21%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 162/465 reads (35%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- RAD51AP2 | c.168C>T p.R56= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 82/282 reads (29%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 83/253 reads (33%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 100/298 reads (34%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RBP3 | c.969C>T p.R323= | Silent (SNP) | VAF 24/863 reads (3%) | catalogued as rs782548823; called by muse, mutect2
- RPS10-NUDT3 | c.120G>A p.V40= | Silent (SNP) | VAF 21/228 reads (9%) | called by muse, mutect2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 122/392 reads (31%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 242/792 reads (31%) | called by muse, varscan2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 64/280 reads (23%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 79/250 reads (32%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/175 reads (45%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 96/278 reads (35%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SRCIN1 | c.1119G>A p.S373= (on ENST00000621492; = p.S339= on NM_025248.3) | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 131/431 reads (30%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 90/288 reads (31%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 80/240 reads (33%) | called by muse, mutect2, varscan2
- TEX51 | c.144A>G p.Q48= | Silent (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 114/315 reads (36%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- TMTC2 | c.2394C>T p.A798= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as rs189664933, COSV100337843; called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRIM37 | c.1503G>A p.E501= | Silent (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 104/319 reads (33%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- TXLNB | c.1608C>T p.A536= | Silent (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- TXNDC5 | c.1131C>T p.A377= | Silent (SNP) | VAF 21/394 reads (5%) | catalogued as rs776991894, COSV51664596, COSV51671965; called by muse, mutect2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 179/613 reads (29%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 75/391 reads (19%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 60/214 reads (28%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 83/210 reads (40%) | called by muse, mutect2, varscan2
- WDR62 | c.966C>A p.A322= | Silent (SNP) | VAF 38/333 reads (11%) | called by muse, mutect2, varscan2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 158/444 reads (36%) | called by muse, mutect2, varscan2
- YTHDC2 | c.2139C>A p.S713= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- ZAN | c.5619G>A p.A1873= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs755433598; called by muse, mutect2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 77/281 reads (27%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 70/227 reads (31%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3812C>T | RNA (SNP) | VAF 28/325 reads (9%) | catalogued as rs754938205; called by muse, mutect2
- AC068587.7 | n.128G>T | RNA (SNP) | VAF 46/414 reads (11%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 53/181 reads (29%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 64/215 reads (30%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 107/341 reads (31%) | called by muse, mutect2, varscan2
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 9/84 reads (11%) | catalogued as rs770626634; called by mutect2, pindel, varscan2*
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 138/835 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 116/368 reads (32%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 66/229 reads (29%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 4/37 reads (11%) | catalogued as rs1383985581; called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 78/249 reads (31%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 45/160 reads (28%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 40/129 reads (31%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 59/411 reads (14%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 84/307 reads (27%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 102/399 reads (26%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DNAH14 | c.1033-4525T>C | Intron (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 73/256 reads (29%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EBAG9 | c.429+706G>A | Intron (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 16/92 reads (17%) | catalogued as rs1446348498; called by mutect2, pindel
- ENAH | c.803-282del | Intron (DEL) | VAF 46/281 reads (16%) | called by mutect2, pindel, varscan2
- ERGIC3 | c.367+751A>T | Intron (SNP) | VAF 12/215 reads (6%) | called by muse, mutect2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 78/415 reads (19%) | called by muse, mutect2, varscan2
- FMO6P | n.1375G>T | RNA (SNP) | VAF 24/548 reads (4%) | catalogued as rs1462308165; called by muse, mutect2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 97/257 reads (38%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 72/259 reads (28%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 40/144 reads (28%) | catalogued as COSV67183745; called by mutect2, varscan2
- KIAA1109 | c.2793+17A>G | Intron (SNP) | VAF 12/368 reads (3%) | called by muse, mutect2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 66/258 reads (26%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LINC02649 | n.309G>A | RNA (SNP) | VAF 15/239 reads (6%) | catalogued as rs201663195; called by muse, mutect2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 18/171 reads (11%) | called by mutect2, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 59/205 reads (29%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 12/62 reads (19%) | catalogued as rs767804788; called by muse, mutect2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 38/117 reads (32%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 107/320 reads (33%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 10/41 reads (24%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 61/375 reads (16%) | catalogued as rs1305952989, COSV58516256; called by muse, mutect2, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 38/114 reads (33%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 15/91 reads (16%) | catalogued as rs749732874; called by mutect2, pindel, varscan2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 62/212 reads (29%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 46/118 reads (39%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 43/184 reads (23%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 20/305 reads (7%) | catalogued as rs528570028; called by muse, mutect2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 165/638 reads (26%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 39/126 reads (31%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 28/84 reads (33%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 56/220 reads (25%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 44/149 reads (30%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- PPP4R1L | n.979+27G>T | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 115/267 reads (43%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 87/476 reads (18%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 72/268 reads (27%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 75/254 reads (30%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 38/124 reads (31%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 182/625 reads (29%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 96/525 reads (18%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 51/323 reads (16%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel
- STAB1 | c.4364-40del | Intron (DEL) | VAF 44/120 reads (37%) | called by mutect2, pindel, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 33/250 reads (13%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 45/175 reads (26%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 20/74 reads (27%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 36/136 reads (26%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 43/164 reads (26%) | called by mutect2, pindel, varscan2
